Somatic mutation profile of tumor specimen TARGET-30-PANUKV-01A (aliquot TARGET-30-PANUKV-01A-01W) from TARGET case TARGET-30-PANUKV, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.1 years (1,486 days).
Specimen TARGET-30-PANUKV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b5fd966-38dc-4000-8019-4639afa94bb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANUKV-10A (Blood Derived Normal), aliquot TARGET-30-PANUKV-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a60befa0-8c81-459c-9dcc-d72f7175e993

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLK | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV52052181; called by muse, mutect2, varscan2
- CERCAM | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs201331661, COSV65710966; called by muse, mutect2, varscan2
- DUSP4 | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53546201; called by muse, mutect2
- LILRB1 | c.733T>A p.S245T (on ENST00000427581; = p.S209T on NM_006669.6) | Missense Mutation (SNP) | VAF 132/173 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61117926; called by muse, mutect2, varscan2
- TRIM44 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54982296, COSV54984092; called by muse, mutect2, varscan2
- FZD8 | c.1173C>A p.T391= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- MFN1 | c.678G>T p.R226= | Silent (SNP) | VAF 44/150 reads (29%) | catalogued as COSV54939643; called by muse, mutect2, varscan2
